Somatic mutation profile of tumor specimen TCGA-B6-A1KN-01A (aliquot TCGA-B6-A1KN-01A-11D-A13L-09) from TCGA case TCGA-B6-A1KN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-B6-A1KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b02a8b-aa88-4d08-afe6-7df4f757b773.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A1KN-10A (Blood Derived Normal), aliquot TCGA-B6-A1KN-10A-01D-A188-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65cdbe3b-c8c8-4ea6-88a4-7b062548b7ac

The open-access MAF lists 61 somatic variants for this specimen: 51 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 42, Silent 10, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLC1 | c.714+1G>A p.X238_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | catalogued as rs761620701, CS063337, COSV61116471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 50/84 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253942, CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD3 | c.295C>T p.P99S (on ENST00000396553 / NM_001025389.2; = p.P108S on NM_000480.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1252411938, COSV67330303; called by muse, mutect2, varscan2
- AQP8 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54844585; called by muse, mutect2, varscan2
- B3GALT5 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58198274; called by muse, mutect2, varscan2
- BCAT1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53909057; called by muse, mutect2, varscan2
- BCORL1 | c.3571C>A p.Q1191K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.333); catalogued as COSV54392390; called by muse, mutect2, varscan2
- BRPF1 | c.1788T>G p.H596Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.376); catalogued as COSV57403898; called by muse, mutect2, varscan2
- C11orf24 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.661); catalogued as rs758231616, COSV58505215; called by muse, mutect2, varscan2
- C17orf75 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56752476; called by muse, mutect2, varscan2
- CYP4V2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777774802, COSV66505353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DENND2D | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62958725; called by muse, mutect2, varscan2
- DNAJB6 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100055901; called by muse, mutect2
- HSPH1 | c.1863G>T p.M621I | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60710753; called by muse, mutect2, varscan2
- IARS1 | c.3661C>G p.R1221G | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV100986879, COSV65117287; called by muse, mutect2, varscan2
- KCNV1 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99819363; called by muse, mutect2
- KDM2A | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV101284673; called by muse, mutect2, varscan2
- L1CAM | c.2608C>T p.H870Y | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1557090599, COSV62827371; called by muse, mutect2, varscan2
- LNPK | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55822973; called by muse, mutect2, varscan2
- LRP1 | c.12627C>A p.S4209R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.154); catalogued as rs1165664955, COSV54505547; called by muse, mutect2
- MIA2 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 34/582 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99696892; called by muse, mutect2
- MKRN3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs765827283, COSV100091493, COSV58809083; called by muse, mutect2, varscan2
- MMAA | c.1167T>G p.I389M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV55579437; called by muse, mutect2, varscan2
- MTERF4 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV54088388; called by muse, mutect2, varscan2
- MUC17 | c.4934G>A p.S1645N | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.134); catalogued as rs1302205491, COSV100073211, COSV60283431, COSV60283750; called by muse, mutect2, varscan2
- NOL12 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV63030844; called by muse, mutect2, varscan2
- NT5E | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs980504395, COSV57627740; called by muse, mutect2, varscan2
- OLFM2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309372108, COSV53429194; called by muse, mutect2
- POP1 | c.2071A>G p.K691E | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100856064; called by muse, mutect2
- PPP1R3A | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | catalogued as COSV52877515; called by muse, mutect2, varscan2
- PRSS53 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760392898, COSV54923446; called by muse, mutect2, varscan2
- SASS6 | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV54927104; called by muse, mutect2, varscan2
- SASS6 | c.544C>G p.R182G | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99791032; called by muse, mutect2
- SCYL2 | c.2686A>T p.M896L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV62568055; called by muse, mutect2, varscan2
- SHROOM4 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV56786549; called by muse, varscan2
- STAT4 | c.2218_2219del p.A740Nfs*8 | Frame Shift Del (DEL) | VAF 33/178 reads (19%) | catalogued as COSV61828741; called by mutect2, pindel, varscan2
- SUCO | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 33/214 reads (15%) | catalogued as COSV99743557; called by muse, mutect2, varscan2
- SURF6 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs587638964, COSV100921204; called by muse, mutect2
- TAS2R42 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV62084464; called by muse, mutect2, varscan2
- TBC1D31 | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 66/760 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99783117, COSV99783126; called by muse, mutect2
- TBC1D4 | c.2619A>C p.R873S | Missense Mutation (SNP) | VAF 101/141 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV66488293; called by muse, mutect2, varscan2
- TMCO6 | c.796A>C p.I266L | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52799318; called by muse, mutect2, varscan2
- TMEM120A | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs782555331, COSV58693647; called by muse, mutect2, varscan2
- UBAC2 | c.109T>C p.C37R (on ENST00000403766 / NM_001144072.2; = p.T78= on NM_177967.4) | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV63117409; called by muse, mutect2, varscan2
- VCPIP1 | c.647A>C p.D216A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60046414; called by muse, mutect2, varscan2
- ZBTB11 | c.2067C>G p.I689M | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV100465436, COSV57244419; called by muse, mutect2, varscan2
- ZNF366 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV59214427; called by muse, mutect2, varscan2
- ZNF687 | c.3077+1G>T p.X1026_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | catalogued as COSV99650069; called by muse, mutect2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 18/70 reads (26%) | called by pindel, varscan2
- ANKHD1-EIF4EBP3 | c.6752_6767del p.G2251Dfs*164 | Frame Shift Del (DEL) | VAF 99/354 reads (28%) | called by mutect2, pindel, varscan2
- PRKDC | c.10926dup p.H3643Tfs*8 | Frame Shift Ins (INS) | VAF 43/165 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF9 | c.513C>T p.N171= | Silent (SNP) | VAF 57/337 reads (17%) | catalogued as rs782684706, COSV53636105; called by muse, mutect2, varscan2
- CUBN | c.9195G>C p.L3065= | Silent (SNP) | VAF 105/205 reads (51%) | catalogued as COSV64710966; called by muse, mutect2, varscan2
- GALNT18 | c.1041G>A p.L347= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs779677454, COSV57145995; called by muse, mutect2, varscan2
- PCDHGA3 | c.2265C>T p.H755= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV53927196; called by muse, mutect2
- PPEF1 | c.1257G>A p.V419= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV62995375; called by muse, mutect2, varscan2
- RIT1 | c.189T>A p.R63= | Silent (SNP) | VAF 96/181 reads (53%) | catalogued as COSV64171003; called by muse, mutect2, varscan2
- SYT11 | c.1074C>A p.I358= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV64173877; called by muse, mutect2, varscan2
- TBC1D1 | c.1269T>C p.N423= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV54716085; called by muse, mutect2, varscan2
- TEX37 | c.111G>A p.T37= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as rs370424706; called by muse, mutect2, varscan2
- ZNF607 | c.2001T>C p.H667= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as rs747818320, COSV67696468; called by muse, mutect2, varscan2
